Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8CD, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8CD-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

Temporary Copy

Case #
Collected
Ordered by

Page 1 of 2

Patient

ID

Location

ACCESSION

Submitting Physician

Clinical History

This man has an ill-defined mass lesion in the right anterior temporal lobe with gyral effacement but no enhancement.

Diagnosis

1. BRAIN, "ANTERIOR TEMPORAL TUMOR," SPECIMEN #1, BIOPSY : ANAPLASTIC ASTROCYTOMA, WHO GRADE III (SEE COMMENTS).
2. BRAIN, "ANTERIOR TEMPORAL TUMOR," SPECIMEN #2, RESECTION : ANAPLASTIC ASTROCYTOMA, WHO GRADE III (SEE COMMENTS).
3. BRAIN, "POST MRI TUMOR," SPECIMEN #3, BIOPSY : ANAPLASTIC ASTROCYTOMA, WHO GRADE III (SEE COMMENTS).

I certify that I personally conducted the diagnostic evaluation on the above specimens and have rendered the above diagnosis(es):

electronic signature

ICD0-3

anaplastic astrocytoma, grade III
9401/3
Site: Brain, supratentorial NOS
path C71.0
Brain, temporal lobe C71.2
9/27/13

For questions regarding this case, call

Comments

This case has also been reviewed at the
Their report, which is available in the
concur with this diagnosis.

Frozen Section Diagnosis

Frozen section diagnosis per : 1FA - "Brain tissue with increased cellularity, no definite evidence of tumor. Defer to permanents."

Gross Description

This specimen is received in three containers, each labeled with the patient's name and medical record number.

Part one is received fresh for intraoperative frozen section, labeled "anterior temporal tumor", and consists of a 0.9 x 0.7 x 0.4 cm pink soft tissue fragment. Approximately half the specimen is submitted for frozen section and subsequently for permanents in cassette 1FA. The remaining tissue is entirely submitted in cassette 1A.

Part two is received in formalin, labeled "anterior temporal tumor", and consists of a 3 x 2.2 x 1 cm aggregate of tan soft tissue fragments. The specimen is sectioned and entirely submitted in cassettes 2A-2C.

Part three is received in formalin, labeled "post MRI tumor", and consists of a 0.5 x 0.5 x 0.2 cm aggregate of tan soft tissue fragments which are submitted entirely in cassette 3A.

[page 2 of 3]
Surg Path Final Report

Temporary Copy

Page 2 of 2

Case

Collected

Ordered by

Patient

ID

Location

Microscopic Examination

Sections of all three specimens are similar and will be described together. They display a glial, infiltrative tumor of astrocytic lineage. The neoplasm is moderately hypercellular and displays mild nuclear pleomorphism and hyperchromasia. Scattered mitotic figures are seen but there is no microvascular proliferation or necrosis present.

Immunohistochemistry for glial fibrillary acidic protein is diffusely positive in the tumor. MIB-1, a proliferation marker, is positive in approximately 10% of the nuclei. IDH-1 staining is negative. All controls are appropriate.

[page 3 of 3]
Addendum Report

Temporary Copy

Page 1 of 1

Case #
Collected
Ordered by

Patient
ID
Location

ACCESSION

Addendum Discussion

Specimen type/procedure: Resection.
Specimen handling: Smear/frozen section/permanent sections.
Laterality: Right.
Tumor site: Brain, temporal lobe.
Histologic type and grade: Anaplastic astrocytoma, WHO Grade III.
Histologic Grade: WHO Grade III.
Margins: Cannot be assessed.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

Source: NCI Genomic Data Commons file 7efd0242-52de-4755-9de9-897d76a99c01 (TCGA-VM-A8CD.CB64BE55-522F-4634-A7B4-17603D50EA3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).